Surgical pathology report (de-identified scan), TCGA case TCGA-44-3918, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-3918-01A (Primary Tumor).

[page 1 of 3]
SPECIMEN

- A. Left upper lobe FS
- B. Node level 5
- C. Node level 1
- D. Left upper lobe
- E. Node level 7
- F. Node level 4
- G. Node level 9

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung mass.

FROZEN SECTION DIAGNOSIS

FSA) Left upper lobe - Poorly differentiated adenocarcinoma.

GROSS DESCRIPTION

A. Submitted fresh for frozen and tissue procurement labeled "left upper lobe" is a wedge resection of pulmonary tissue, which has a small incision previously made within it. The wedge measures maximally 7 x 4 x 3 cm. Next to the incision site there is some puckering of the pleura, which overlies a palpable lung mass. Sutures are removed from the specimen and is then serially sectioned. Sections through the specimen reveals a puckered firm tan tumor mass immediately below the pleural surface measuring maximally 2.2 cm in greatest dimension. Per request, a portion of tissue is submitted for tissue procurement. A portion of tissue is submitted for frozen section. RS-4. B. Received fresh, subsequently fixed in formalin labeled "node level 5" is a 1.2 x 0.5 x 0.5 cm black-red irregular soft tissue fragment which is bisected and entirely submitted in one cassette. AS-1. C. Received in formalin labeled "node level 1" is a 1.5 x 1.5 x 0.6 cm pink black, irregular tissue fragment which is

GROSS DESCRIPTION

bisected and entirely submitted in one cassette. AS-1. D. Received fresh, subsequently fixed in formalin labeled "left upper lobe" is a 20.0 x 6.5 x 3.5 cm remainder of lobe. The specimen is partially covered with violaceous smooth glistening pleura and shows multiple staple lines present throughout the specimen. The specimen is sectioned showing a pink-red spongy cut surface with no discrete gross lesions identified. Multiple black-red hilar nodes are grossly identified. Representative sections of the specimen are submitted as follows:

[page 2 of 3]
BLOCK SUMMARY: 1 - possible hilar lymph node; 2 - vascular and bronchial margins; 3-4 - representative normal. RS-4.

E. Received fresh, subsequently fixed in formalin labeled "node level 7" are two black-red irregular soft tissue fragments which average 0.8 cm in greatest dimension. The specimens

are entirely submitted in one cassette. AS-1.

F. Received fresh, subsequently fixed in formalin labeled "node level 7" is a 0.5 x 0.4 x 0.4 cm gray-pink-black irregular soft tissue fragment which is entirely submitted in one cassette. AS-1.

G. Received in formalin labeled "node level 9" is a 1.2 x 0.7 x 0.5 cm black-gray irregular soft tissue fragment which is bisected and entirely submitted in one cassette. AS-1.

MICROSCOPIC DESCRIPTION

Histologic type: Adenocarcinoma.

Histologic grade: Moderate to poorly differentiated.

Primary tumor (pT): Tumor measures maximally 2.2 cm in size and is confined to the lung (pT1b).

Margins of resection: Bronchial and vascular margins are free of tumor.

MICROSCOPIC DESCRIPTION

Direct extension of tumor: Absent.

Venous (large vessel) invasion: Negative.

Arterial (large vessel) invasion: Negative.

Lymphatic (small vessel) invasion: Negative.

Regional lymph nodes (pN): Hilar lymph nodes and all sampled mediastinal

lymph nodes are negative for metastatic carcinoma (pN0).

Distant metastasis (pM): Cannot be assessed (pMx).

5,3x5,14

[page 3 of 3]
DIAGNOSIS

- A. and D. Lung, left upper lobectomy:
Moderate to poorly differentiated adenocarcinoma.
The tumor is confined to the lung without involvement of the
visceral pleural surface.
Bronchial and vascular margins of resection are free of
tumor.
- Seven bronchial lymph nodes negative for metastatic carcinoma
(0/7).
- B. Lymph node, level 5, resection:
Negative for malignancy.
- C. Lymph node, level 1, resection:
Negative for malignancy.
- E. Lymph node, level 7, resection:
Negative for malignancy.
- F. Lymph node, level 4, resection:
Negative for malignancy.
- G. Lymph node, level 9, resection:

DIAGNOSIS

Negative for malignancy.

--- End Of Report ---

Source: NCI Genomic Data Commons file acf6798b-dee3-437c-bb89-ca70f1d7afab (TCGA-44-3918.DA381E6D-F69D-424F-AB84-5C300CA19435.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).